Somatic mutation profile of tumor specimen TARGET-20-PATBIP-09A (aliquot TARGET-20-PATBIP-09A-01D) from TARGET case TARGET-20-PATBIP, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.1 years (6,253 days).
Specimen TARGET-20-PATBIP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e56f3af-5461-498b-9f7a-2e0b9d8a42cf.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATBIP-14A (Bone Marrow Normal), aliquot TARGET-20-PATBIP-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34137f22-68da-444c-9af6-82323453d9bd

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SETD2 | c.4874G>A p.R1625H | Missense Mutation (SNP) | VAF 63/182 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57431794, COSV57438402; called by muse, mutect2, varscan2
- CEBPA | c.922_925delinsA p.V308_E309delinsK | In Frame Del (DEL) | VAF 53/140 reads (38%) | called by pindel, varscan2*
- STAG2 | c.3467+4_3467+7del p.X1156_splice | Splice Site (DEL) | VAF 83/231 reads (36%) | called by pindel, varscan2
